Somatic mutation profile of tumor specimen ALCH-AEJI-TTP1-A (aliquot ALCH-AEJI-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEJI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.5 years (25,372 days).
Specimen ALCH-AEJI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16e271ba-4582-4fee-94ca-5f39656153ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJI-NB1-A (Blood Derived Normal), aliquot ALCH-AEJI-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5916b711-ac50-49f6-9044-15b2238681dd

The open-access MAF lists 72 somatic variants for this specimen: 43 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 20, Nonsense Mutation 6, Intron 5, 5'UTR 1, 3'UTR 1, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 66/690 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 334/962 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BOD1L1 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs1282334783; called by muse, mutect2, varscan2
- CPAMD8 | c.5017C>T p.R1673W (on ENST00000651564; = p.R1626W on NM_015692.5) | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV71595748; called by muse, mutect2
- GLDC | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 50/457 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1563852496, COSV58678315, COSV58682679; called by muse, mutect2, varscan2
- HEATR5A | c.4880C>A p.S1627Y | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as COSV66343996; called by muse, mutect2
- INSRR | c.3692C>T p.P1231L | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs778994457, COSV63873622; called by muse, mutect2, varscan2
- KDM3B | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV100069587; called by muse, mutect2
- NOVA1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 58/746 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99946754; called by muse, mutect2
- PIK3C2A | c.4781C>T p.P1594L | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56401766; called by muse, mutect2
- PLXNB3 | c.4016G>A p.R1339H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782437849, COSV62795194; called by muse, mutect2, varscan2
- POP5 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 48/525 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1249300389; called by muse, mutect2
- RELN | c.4726C>T p.R1576* | Nonsense Mutation (SNP) | VAF 14/318 reads (4%) | catalogued as COSV58987651; called by muse, mutect2
- SHROOM4 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99173402; called by muse, mutect2
- SV2C | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as COSV59220232; called by muse, mutect2
- TMEM63B | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1373983293, COSV99442157; called by muse, mutect2
- ACOX1 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 20/622 reads (3%) | called by muse, mutect2
- AKAP13 | c.2587A>G p.T863A | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2
- ANK2 | c.10836G>C p.Q3612H | Missense Mutation (SNP) | VAF 24/604 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BOD1L1 | c.2941G>T p.A981S | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- CFAP46 | c.2190G>T p.E730D | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ELN | c.793A>T p.K265* | Nonsense Mutation (SNP) | VAF 71/445 reads (16%) | called by muse, mutect2, varscan2
- FAM184B | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2
- FGF7 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- FRMPD4 | c.2486C>G p.S829C | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2
- GLI2 | c.2896C>T p.R966W (on ENST00000361492 / NM_001374353.1; = p.R983W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/461 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- HTT | c.2452G>T p.E818* | Nonsense Mutation (SNP) | VAF 16/503 reads (3%) | called by muse, mutect2
- IRF4 | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- LIMK1 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.065); called by muse, varscan2
- LRRC8A | c.838T>A p.C280S | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- MKRN3 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.259); called by muse, mutect2
- NEFH | c.2309C>A p.A770E | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); called by muse, varscan2
- OR2M3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 46/787 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.248); called by muse, mutect2
- PDE12 | c.1318C>G p.L440V | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RAI2 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- RBM10 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 47/306 reads (15%) | called by muse, mutect2, varscan2
- SIK2 | c.1319G>A p.C440Y | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SYN3 | c.714C>A p.V238= | Splice Region (SNP) | VAF 27/198 reads (14%) | called by muse, mutect2, varscan2
- TNFSF11 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 52/748 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); called by muse, mutect2
- TRIM24 | c.2852G>T p.R951I (on ENST00000343526 / NM_015905.3; = p.R917I on NM_003852.4) | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- USP33 | c.1241A>T p.D414V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); called by muse, varscan2
- XIRP1 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFP92 | c.927C>A p.H309Q | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CAMK1D | c.75C>T p.F25= | Silent (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- CRYGB | c.21C>T p.Y7= | Silent (SNP) | VAF 58/240 reads (24%) | catalogued as rs758440322, COSV53680421; called by muse, mutect2, varscan2
- DLL3 | c.1353C>T p.L451= | Silent (SNP) | VAF 24/492 reads (5%) | catalogued as rs1415685121; called by muse, mutect2
- DUSP8 | c.492C>T p.I164= | Silent (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- MAGEA10 | c.786C>T p.L262= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- MED13L | c.693C>G p.A231= | Silent (SNP) | VAF 97/503 reads (19%) | called by muse, mutect2, varscan2
- OR8S1 | c.579C>T p.S193= | Silent (SNP) | VAF 42/328 reads (13%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1548C>T p.L516= | Silent (SNP) | VAF 40/1047 reads (4%) | called by muse, mutect2
- PCDHB8 | c.1824C>G p.L608= | Silent (SNP) | VAF 36/1188 reads (3%) | catalogued as COSV50809509; called by muse, mutect2
- PHKA2 | c.1080C>T p.I360= | Silent (SNP) | VAF 22/647 reads (3%) | catalogued as rs1485599457, COSV101177663; called by muse, mutect2
- RECQL5 | c.93G>A p.T31= | Silent (SNP) | VAF 22/342 reads (6%) | catalogued as rs776148261; called by muse, mutect2
- RYR3 | c.2472C>A p.V824= | Silent (SNP) | VAF 23/507 reads (5%) | called by muse, mutect2
- SPTA1 | c.2595T>C p.F865= | Silent (SNP) | VAF 42/393 reads (11%) | called by muse, mutect2, varscan2
- STAT6 | c.594G>A p.L198= | Silent (SNP) | VAF 36/452 reads (8%) | called by muse, mutect2
- TBX1 | c.963G>A p.S321= | Silent (SNP) | VAF 20/286 reads (7%) | catalogued as rs1268727769; called by muse, mutect2
- TRIM29 | c.384C>T p.R128= | Silent (SNP) | VAF 32/428 reads (7%) | catalogued as COSV59281982; called by muse, mutect2
- TRO | c.325C>T p.L109= | Silent (SNP) | VAF 24/432 reads (6%) | called by muse, mutect2
- USP41 | c.717G>A p.G239= | Silent (SNP) | VAF 72/488 reads (15%) | called by muse, mutect2, varscan2
- WDR87 | c.339C>T p.I113= | Silent (SNP) | VAF 22/679 reads (3%) | called by muse, mutect2
- ZNF317 | c.1371G>A p.A457= | Silent (SNP) | VAF 19/274 reads (7%) | catalogued as rs775432032; called by muse, mutect2
- ACTN2 | c.-32C>T | 5'UTR (SNP) | VAF 19/373 reads (5%) | catalogued as COSV63974083; called by muse, mutect2
- CELF2 | c.1076-2262G>C | Intron (SNP) | VAF 35/382 reads (9%) | called by muse, mutect2
- DENND2A | c.*24C>A | 3'UTR (SNP) | VAF 12/147 reads (8%) | called by muse, mutect2
- KANSL3 | c.1086+12C>T | Intron (SNP) | VAF 22/378 reads (6%) | called by muse, mutect2
- MEFV | c.1610+50T>A | Intron (SNP) | VAF 15/315 reads (5%) | catalogued as rs1255435530; called by muse, mutect2
- RBM3 | chrX:48574516 del T | 5'Flank (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel
- TOR1A | c.444+97G>A | Intron (SNP) | VAF 16/426 reads (4%) | catalogued as rs978090391; called by muse, mutect2
- TTC3P1 | n.4941G>T | RNA (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- VPS8 | c.2146+34C>T | Intron (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
